Somatic mutation profile of tumor specimen 0DQFJ4 from CCDI case PBCESS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.7 years (4,640 days).
Specimen 0DQFJ4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50a1fcc6-d615-4d5c-9a79-cc4e6e4be97c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQFIW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/781992db-43c3-4b7c-a611-1c2332f139aa

The open-access MAF lists 853 somatic variants for this specimen: 516 protein-altering or splice-affecting, 164 silent, 173 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 415, Silent 164, Intron 98, Frame Shift Del 48, 3'UTR 44, Nonsense Mutation 17, 5'UTR 17, Splice Region 14, Frame Shift Ins 14, 5'Flank 7, Splice Site 5, RNA 4.

Variants (750 of 853; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 94/115 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193922097, CM950030, COSV54385597; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4600C>T p.R1534* (on ENST00000358273 / NM_001042492.3; = p.R1513* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 144/373 reads (39%) | catalogued as rs760703505, CM941093, COSV62191852; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.5305C>T p.R1769* (on ENST00000358273 / NM_001042492.3; = p.R1748* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 157/400 reads (39%) | catalogued as rs876657714, CM941094, COSV62196320; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 235/553 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 202/407 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ZEB2 | c.2083C>T p.R695* | Nonsense Mutation (SNP) | VAF 220/507 reads (43%) | catalogued as rs137852981, CM013801, COSV57956692; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD11 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 228/552 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs374778806; called by muse, mutect2, varscan2
- ABTB2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 26/783 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54392851; called by muse, mutect2
- ACAN | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 229/555 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs749720584, COSV61368045; called by muse, mutect2, varscan2
- ACKR2 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 285/671 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56176699; called by muse, mutect2, varscan2
- ACOX3 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 220/453 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1355657496; called by muse, mutect2, varscan2
- ACTL10 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 87/206 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1207431683; called by muse, mutect2, varscan2
- ADAMTS5 | c.1149C>G p.D383E | Missense Mutation (SNP) | VAF 23/720 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV53179228; called by muse, mutect2
- ADAMTSL4 | c.2471C>T p.A824V | Missense Mutation (SNP) | VAF 117/278 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.269); catalogued as rs377554910; called by muse, mutect2, varscan2
- ADGRA1 | c.890C>G p.T297S | Missense Mutation (SNP) | VAF 92/134 reads (69%) | SIFT tolerated (0.42); PolyPhen benign (0.241); catalogued as rs1229267231; called by muse, mutect2, varscan2
- ADPRM | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 279/704 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as rs199523732; called by muse, mutect2, varscan2
- AFF1 | c.3262G>A p.A1088T | Missense Mutation (SNP) | VAF 26/528 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.04); catalogued as rs965718319, COSV57120573; called by muse, mutect2
- AGR2 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 190/497 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs1158959133; called by muse, mutect2, varscan2
- AK8 | c.36dup p.E13Rfs*40 | Frame Shift Ins (INS) | VAF 93/258 reads (36%) | catalogued as rs757477831; called by mutect2, varscan2
- AKR1E2 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 128/308 reads (42%) | catalogued as rs748631440, COSV53629928; called by muse, mutect2, varscan2
- AL645922.1 | c.3718G>A p.A1240T | Missense Mutation (SNP) | VAF 227/509 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs754336626, COSV64888461; called by muse, mutect2, varscan2
- ALDH1A1 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 161/385 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs539236717; called by muse, mutect2, varscan2
- ANK2 | c.5145del p.E1716Rfs*22 | Frame Shift Del (DEL) | VAF 233/557 reads (42%) | catalogued as COSV52180535; called by mutect2, varscan2
- ANKS1B | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 264/604 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs759628814; called by muse, mutect2
- ANLN | c.958del p.T320Lfs*6 | Frame Shift Del (DEL) | VAF 211/492 reads (43%) | catalogued as COSV56074074; called by mutect2, varscan2
- AP1B1 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 223/517 reads (43%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as rs776595684; called by muse, mutect2, varscan2
- APBB1IP | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 169/428 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.618); catalogued as rs1024493265; called by muse, mutect2, varscan2
- ARAP2 | c.4651C>T p.R1551C | Missense Mutation (SNP) | VAF 221/519 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs775209671, COSV100394643; called by muse, mutect2, varscan2
- ARFGEF3 | c.5641C>T p.R1881W | Missense Mutation (SNP) | VAF 106/232 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs977816816; called by muse, mutect2, varscan2
- ATAD3B | c.894C>T p.R298= (on ENST00000308647; = p.R404= on NM_031921.6 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 50/232 reads (22%) | catalogued as rs368162702; called by muse, mutect2, varscan2
- ATP10D | c.799G>A p.V267M | Missense Mutation (SNP) | VAF 205/538 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs185611178, COSV56707787; called by muse, mutect2, varscan2
- ATXN3 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 237/577 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs750538982; called by muse, mutect2, varscan2
- B4GALNT4 | c.1591C>T p.R531W | Missense Mutation (SNP) | VAF 106/249 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs762492270, COSV57326508; called by muse, mutect2, varscan2
- BCLAF1 | c.2687G>T p.G896V | Missense Mutation (SNP) | VAF 196/486 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1357903517; called by mutect2, varscan2
- BDH1 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 272/644 reads (42%) | catalogued as rs1354429802, COSV64018000; called by muse, mutect2, varscan2
- BPIFB2 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 139/323 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs372044696; called by muse, mutect2, varscan2
- BRINP1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 287/608 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1160419277, COSV56306806; called by muse, mutect2, varscan2
- BTN2A2 | c.69_71del p.L24del | In Frame Del (DEL) | VAF 190/490 reads (39%) | catalogued as rs751776181; called by mutect2, varscan2
- C10orf120 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1431253930, COSV61491778, COSV61492642; called by muse, mutect2
- C1orf159 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 119/332 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as rs1341697804; called by muse, mutect2, varscan2
- C6orf118 | c.500del p.G167Afs*16 | Frame Shift Del (DEL) | VAF 100/264 reads (38%) | catalogued as COSV57814827; called by mutect2, varscan2
- CACHD1 | c.3547C>T p.R1183C | Missense Mutation (SNP) | VAF 185/436 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs756541202, COSV51550217; called by muse, mutect2, varscan2
- CACNA1D | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 310/767 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as rs533046755, COSV55456930, COSV55467087; called by muse, mutect2, varscan2
- CCDC168 | c.3805dup p.T1269Nfs*38 | Frame Shift Ins (INS) | VAF 134/360 reads (37%) | catalogued as rs773171420; called by mutect2, varscan2
- CCDC173 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 260/629 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs183570726; called by muse, mutect2, varscan2
- CCDC80 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 104/258 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750998985; called by muse, varscan2
- CCDC88C | c.4441+8C>T | Splice Region (SNP) | VAF 121/265 reads (46%) | catalogued as rs767367406; called by muse, mutect2, varscan2
- CCDC97 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 122/288 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs752646666, COSV54189651; called by muse, mutect2, varscan2
- CCN3 | c.1057A>G p.T353A | Missense Mutation (SNP) | VAF 234/565 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV52383844; called by muse, mutect2, varscan2
- CD68 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 161/423 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs751640523; called by muse, mutect2, varscan2
- CDC16 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 228/546 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as rs770502085, COSV52957933; called by muse, mutect2
- CDH20 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 155/344 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761069057, COSV53020606; called by muse, mutect2, varscan2
- CDH4 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 165/440 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs759379228, COSV64645806; called by muse, mutect2, varscan2
- CFAP54 | c.4253del p.K1418Rfs*4 | Frame Shift Del (DEL) | VAF 230/472 reads (49%) | catalogued as rs1274191949; called by mutect2, varscan2
- CFAP77 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs765507051, COSV58011972; called by muse, mutect2, varscan2
- CHD6 | c.3295C>T p.R1099W | Missense Mutation (SNP) | VAF 78/518 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761163370, COSV58555294; called by muse, mutect2, varscan2
- CHMP7 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 224/545 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs748289598; called by muse, mutect2, varscan2
- CHRNA4 | c.1825G>A p.V609I | Missense Mutation (SNP) | VAF 164/378 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs201168195; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CIT | c.4771C>T p.R1591C | Missense Mutation (SNP) | VAF 148/281 reads (53%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as rs759128008, COSV99948420, COSV99948538; called by muse, mutect2, varscan2
- CLCA4 | c.1953C>T p.G651= | Splice Region (SNP) | VAF 116/300 reads (39%) | catalogued as rs138241227; called by muse, mutect2, varscan2
- CLIP3 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 109/251 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.267); catalogued as COSV62112754; called by muse, mutect2, varscan2
- CMTR1 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 143/310 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs760920297; called by muse, mutect2, varscan2
- CMYA5 | c.6628G>A p.V2210I | Missense Mutation (SNP) | VAF 255/592 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); catalogued as rs751513243, COSV71404031; called by muse, mutect2, varscan2
- COG2 | c.380del p.K127Rfs*5 | Frame Shift Del (DEL) | VAF 206/478 reads (43%) | catalogued as rs1188081815, COSV100794718; called by mutect2, varscan2
- COG4 | c.2093C>A p.S698Y | Missense Mutation (SNP) | VAF 184/412 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55375765; called by muse, mutect2, varscan2
- COL1A2 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 25/416 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72656385, CM062544, COSV51954273; called by muse, mutect2
- COL6A1 | c.3077C>T p.A1026V | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as rs767414809; called by muse, mutect2, varscan2
- COL6A2 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 113/433 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs775799847; called by muse, mutect2, varscan2
- COMP | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 12/377 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.895); catalogued as COSV55874683; called by muse, mutect2
- COPS7A | c.655A>C p.T219P | Missense Mutation (SNP) | VAF 184/438 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV57527080; called by muse, mutect2, varscan2
- CRB2 | c.2637del p.A880Pfs*261 | Frame Shift Del (DEL) | VAF 146/314 reads (46%) | catalogued as rs1264148565; called by mutect2, varscan2
- CROCC2 | c.4426C>T p.R1476C | Missense Mutation (SNP) | VAF 200/506 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs774985974; called by muse, varscan2
- CRTAP | c.797A>G p.H266R | Missense Mutation (SNP) | VAF 92/240 reads (38%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.99); catalogued as rs1404086318; called by muse, mutect2, varscan2
- CSPG4 | c.5980G>A p.G1994R | Missense Mutation (SNP) | VAF 64/85 reads (75%) | SIFT tolerated (0.86); PolyPhen benign (0.011); catalogued as rs1406907988; called by muse, mutect2, varscan2
- CTDSP1 | c.657+8C>T | Splice Region (SNP) | VAF 175/394 reads (44%) | catalogued as rs745425430; called by muse, mutect2, varscan2
- CTNND2 | c.2016G>A p.M672I | Missense Mutation (SNP) | VAF 209/561 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs1303769724; called by muse, mutect2, varscan2
- CTTNBP2 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 197/525 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs776837687, COSV50392883; called by muse, mutect2, varscan2
- CYP2F1 | c.1152+4C>T | Splice Region (SNP) | VAF 163/437 reads (37%) | catalogued as rs1370992858; called by muse, mutect2, varscan2
- D2HGDH | c.1285G>A p.V429M | Missense Mutation (SNP) | VAF 164/451 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs769624048, COSV58321773; called by muse, mutect2, varscan2
- DCAF8 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 182/468 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs564633806; called by muse, mutect2, varscan2
- DENND6B | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 158/392 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs901355479; called by muse, mutect2, varscan2
- DHX15 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 249/655 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1390375046, COSV61026699; called by muse, mutect2, varscan2
- DIP2A | c.3725G>A p.R1242H | Missense Mutation (SNP) | VAF 139/326 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs940141568; called by muse, mutect2, varscan2
- DLK1 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1186718844, COSV100375015; called by muse, mutect2, varscan2
- DNAH10 | c.4274C>T p.T1425M (on ENST00000409039; = p.T1364M on NM_207437.3) | Missense Mutation (SNP) | VAF 54/800 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1313910087, COSV68993426; called by muse, mutect2
- DNM3 | c.175C>G p.R59G | Missense Mutation (SNP) | VAF 262/582 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100798594, COSV62454976; called by muse, mutect2, varscan2
- DOCK9 | c.2593G>A p.A865T (on ENST00000376460 / NM_001366676.2; = p.A866T on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 137/336 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0.04); catalogued as rs377041723, COSV59630108; called by muse, varscan2
- DSCAML1 | c.754G>A p.A252T (on ENST00000321322; = p.A192T on NM_020693.4) | Missense Mutation (SNP) | VAF 159/386 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs142110596, COSV58389573; called by muse, mutect2, varscan2
- DZANK1 | c.1229G>A p.R410H (on ENST00000262547 / NM_001099407.1; = p.R211H on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 193/492 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs750727435, COSV52748522, COSV52749420; called by muse, mutect2, varscan2
- E2F8 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 200/511 reads (39%) | catalogued as rs1478433303, COSV51462299; called by muse, mutect2, varscan2
- EFCAB7 | c.1846C>T p.R616* | Nonsense Mutation (SNP) | VAF 120/304 reads (39%) | catalogued as rs1228928975, COSV64314325; called by muse, mutect2, varscan2
- EIF2D | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 126/347 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs150459038; called by muse, mutect2, varscan2
- EPHB1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 160/386 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1415689583, COSV67659496; called by muse, varscan2
- ERBB4 | c.3471A>C p.K1157N | Missense Mutation (SNP) | VAF 117/273 reads (43%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.738); catalogued as COSV100726158; called by muse, mutect2, varscan2
- ERICH1 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 210/489 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs755450433, COSV50637724; called by muse, mutect2
- ESPNL | c.1022T>C p.F341S | Missense Mutation (SNP) | VAF 136/400 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.23); catalogued as rs1393388562, COSV58033144; called by muse, mutect2
- EXTL3 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 128/300 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs199979119; called by muse, mutect2, varscan2
- F5 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 214/541 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs894933282, COSV100888844; called by muse, mutect2, varscan2
- FAM47A | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 135/177 reads (76%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.669); catalogued as rs759132819, COSV60500234; called by muse, mutect2, varscan2
- FAM71B | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 117/349 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs752153945, COSV57228020; called by muse, mutect2, varscan2
- FAT1 | c.6866C>T p.A2289V | Missense Mutation (SNP) | VAF 158/391 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs562612394, COSV71672054; called by muse, mutect2, varscan2
- FAT4 | c.12646C>T p.R4216C | Missense Mutation (SNP) | VAF 290/747 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs769772147; called by muse, mutect2, varscan2
- FATE1 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 369/480 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.208); catalogued as rs144817068, COSV64849161; called by muse, mutect2, varscan2
- FOXA3 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 167/343 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1272245829; called by muse, mutect2, varscan2
- G2E3 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 125/334 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as rs139585540; called by muse, mutect2, varscan2
- G2E3 | c.1081del p.T361Lfs*16 | Frame Shift Del (DEL) | VAF 134/339 reads (40%) | catalogued as rs751355614, COSV52840527; called by mutect2, varscan2
- GGTLC1 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 193/500 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as rs746307097, COSV53848829; called by muse, mutect2, varscan2
- GLI2 | c.4621G>A p.A1541T (on ENST00000361492 / NM_001374353.1; = p.A1558T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 237/588 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as rs200551009; called by muse, mutect2, varscan2
- GLP1R | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 102/244 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.293); catalogued as rs937676680; called by muse, mutect2, varscan2
- GLUD2 | c.1192G>T p.A398S | Missense Mutation (SNP) | VAF 408/516 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV60152286; called by mutect2, varscan2
- GNA14 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 172/423 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs745646033; called by muse, mutect2, varscan2
- GNGT1 | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 30/755 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV50352525; called by muse, mutect2
- GOLGA2 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 133/348 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as rs752893565, COSV104436560; called by muse, mutect2, varscan2
- GPR158 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 227/584 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765240286, COSV66271463; called by muse, mutect2, varscan2
- GPT2 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 174/418 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs781284492; called by muse, mutect2, varscan2
- GSE1 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 165/448 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.354); catalogued as rs377684294; called by muse, mutect2, varscan2
- GTF3C1 | c.5473G>A p.A1825T | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs779758810; called by muse, mutect2
- GUK1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 145/366 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373280418, COSV57158579; called by muse, mutect2, varscan2
- H1-6 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 233/539 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs746084928, COSV58091447; called by muse, mutect2, varscan2
- H3C1 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 15/321 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs1267542423, COSV55119627; called by muse, mutect2
- HDAC7 | c.2192G>A p.R731H (on ENST00000427332; = p.R770H on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 198/486 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99316775; called by muse, mutect2, varscan2
- HHIPL2 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 206/480 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs144328016, COSV100596484; called by muse, varscan2
- HINT3 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 222/659 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.31); catalogued as COSV57649566; called by muse, mutect2, varscan2
- HIVEP3 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 135/322 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.928); catalogued as rs984979732; called by muse, mutect2, varscan2
- HKDC1 | c.2177C>T p.T726M | Missense Mutation (SNP) | VAF 163/217 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs770837285, COSV63576408, COSV63579796; called by muse, mutect2, varscan2
- HLX | c.1019A>G p.Q340R | Missense Mutation (SNP) | VAF 185/460 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV100854425; called by muse, mutect2
- HMGXB4 | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 252/597 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99329963; called by muse, varscan2
- HNRNPUL2 | c.2110C>T p.R704* | Nonsense Mutation (SNP) | VAF 224/598 reads (37%) | catalogued as rs369405010, COSV57132197; called by muse, mutect2, varscan2
- HS3ST3A1 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 74/311 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs574000502; called by muse, mutect2, varscan2
- HSPA4L | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 177/455 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs768194196, COSV56545185; called by muse, mutect2, varscan2
- HTRA3 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 157/389 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs201531880; called by muse, mutect2, varscan2
- IFT140 | c.3562C>T p.R1188W | Missense Mutation (SNP) | VAF 161/375 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs575196272, COSV63699031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFT140 | c.2885C>T p.A962V | Missense Mutation (SNP) | VAF 73/185 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1371411242, COSV54154500; called by muse, mutect2, varscan2
- IFT172 | c.2963G>A p.R988H | Missense Mutation (SNP) | VAF 296/651 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as rs201853736, COSV99037262; called by muse, mutect2, varscan2
- IGDCC4 | c.2613dup p.T872Hfs*22 | Frame Shift Ins (INS) | VAF 88/130 reads (68%) | catalogued as rs761621429; called by mutect2, varscan2
- ILVBL | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 188/454 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs752708641; called by muse, mutect2, varscan2
- INPP5J | c.2279G>A p.R760H (on ENST00000331075 / NM_001284285.2; = p.R392H on NM_001002837.2) | Missense Mutation (SNP) | VAF 131/346 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs199693963; called by muse, mutect2, varscan2
- INTS1 | c.2527del p.R843Gfs*11 | Frame Shift Del (DEL) | VAF 48/120 reads (40%) | catalogued as rs779930616; called by mutect2, varscan2
- IPO11 | c.716del p.L239Yfs*8 | Frame Shift Del (DEL) | VAF 76/272 reads (28%) | catalogued as COSV100321224; called by mutect2, varscan2
- IPO5 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 172/431 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1367482292, COSV55156041; called by muse, mutect2, varscan2
- ITIH3 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 32/595 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.18); catalogued as rs548417682, COSV69649645; called by muse, mutect2
- IWS1 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 242/593 reads (41%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs745591024, COSV54866801; called by muse, mutect2, varscan2
- KCNC3 | c.1880dup p.A628Sfs*28 | Frame Shift Ins (INS) | VAF 53/125 reads (42%) | catalogued as rs1159900432; called by mutect2, varscan2
- KCNS2 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 151/380 reads (40%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.446); catalogued as rs1488567981; called by muse, mutect2, varscan2
- KIAA1549L | c.3298C>T p.R1100W (on ENST00000321505; = p.R1397W on NM_012194.3) | Missense Mutation (SNP) | VAF 233/623 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757475102, COSV55775832, COSV55777990; called by muse, mutect2, varscan2
- KLF4 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as rs1310912820; called by muse, mutect2, varscan2
- KLF6 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 132/321 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs772132474, COSV51496061; called by muse, mutect2, varscan2
- KRT6C | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 278/697 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); catalogued as rs759012703, COSV52876737; called by muse, mutect2, varscan2
- LENG9 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 110/281 reads (39%) | catalogued as rs997620728, COSV56618126; called by muse, varscan2
- LEXM | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 248/580 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs778325351, COSV64022212; called by muse, mutect2, varscan2
- LGALS13 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 44/873 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1303608067, COSV99695050; called by muse, mutect2
- LHX2 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 137/340 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV101010080; called by muse, mutect2, varscan2
- LHX2 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 136/365 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.049); catalogued as rs973270362; called by muse, mutect2, varscan2
- LRIT3 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 238/547 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1410028604; called by muse, mutect2, varscan2
- LRRC75B | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs369950570, COSV50638165; called by muse, mutect2, varscan2
- LTBP2 | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 122/305 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs765072306, COSV100001196; called by muse, mutect2, varscan2
- LTBP2 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 176/461 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56207416; called by muse, mutect2, varscan2
- LZTR1 | c.1234C>A p.R412S | Missense Mutation (SNP) | VAF 180/456 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV53147792; called by muse, mutect2, varscan2
- MAB21L4 | c.632C>T p.A211V (on ENST00000388934 / NM_001085437.3; = p.A43V on NM_024861.4) | Missense Mutation (SNP) | VAF 127/297 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs377523321; called by muse, mutect2, varscan2
- MAK16 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 153/396 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as rs968732545; called by muse, mutect2, varscan2
- MAP1B | c.6638G>A p.R2213H | Missense Mutation (SNP) | VAF 216/554 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as rs754794035, COSV57100897; called by muse, mutect2, varscan2
- MAP1LC3C | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 28/484 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.245); catalogued as rs867743099, COSV61803856; called by muse, mutect2
- MAP3K10 | c.1945C>T p.R649W | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs746603239; called by muse, mutect2, varscan2
- MED12L | c.3319G>A p.A1107T | Missense Mutation (SNP) | VAF 342/739 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs777002012, COSV56372488; called by muse, mutect2, varscan2
- MEOX1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 128/306 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747977868, COSV59356494; called by muse, varscan2
- MFAP5 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 171/399 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs865910671; called by muse, mutect2, varscan2
- MFSD1 | c.752-1G>T p.X251_splice | Splice Site (SNP) | VAF 135/355 reads (38%) | catalogued as COSV51839760; called by muse, mutect2, varscan2
- MPO | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 117/259 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1399823848, COSV99832857; called by muse, mutect2, varscan2
- MROH1 | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 94/253 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1420416700; called by muse, mutect2, varscan2
- MVB12B | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 100/227 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs760736690; called by muse, mutect2, varscan2
- MYH8 | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 195/496 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1257110531; called by muse, mutect2, varscan2
- MYO15B | c.4466G>A p.R1489Q | Missense Mutation (SNP) | VAF 163/332 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as rs771713966, COSV73874328; called by muse, mutect2, varscan2
- NAPEPLD | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 252/545 reads (46%) | catalogued as rs1166163558; called by muse, mutect2, varscan2
- NAV2 | c.3049G>A p.G1017R (on ENST00000396087 / NM_001244963.2; = p.G994R on NM_145117.5) | Missense Mutation (SNP) | VAF 294/677 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs751090580; called by muse, mutect2, varscan2
- NBAS | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 183/443 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs139067269; called by muse, mutect2, varscan2
- NEK10 | c.2168C>T p.A723V | Missense Mutation (SNP) | VAF 207/485 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.255); catalogued as rs781114388, COSV99835034; called by muse, mutect2, varscan2
- NELL2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 127/337 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs548983604, COSV61575306; called by muse, mutect2, varscan2
- NFRKB | c.1030G>A p.A344T (on ENST00000446488 / NM_001143835.2; = p.A369T on NM_006165.3) | Missense Mutation (SNP) | VAF 221/505 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs764516795, COSV58757285; called by muse, mutect2, varscan2
- NGEF | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 197/547 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs760174723; called by muse, mutect2
- NISCH | c.2609C>T p.T870M | Missense Mutation (SNP) | VAF 104/251 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.813); catalogued as rs778902440; called by muse, mutect2, varscan2
- NLRP1 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 224/547 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs757124919, COSV52562735; called by muse, mutect2, varscan2
- NT5C1B | c.352C>T p.R118C (on ENST00000359846 / NM_001199086.2; = p.R58C on NM_033253.4) | Missense Mutation (SNP) | VAF 182/473 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as rs752112948, COSV100410251; called by muse, mutect2, varscan2
- NUDT13 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 213/283 reads (75%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as COSV61968016; called by muse, mutect2, varscan2
- NUP58 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 113/248 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.116); catalogued as rs1314604684; called by muse, mutect2, varscan2
- OBSCN | c.8569G>A p.V2857M | Missense Mutation (SNP) | VAF 166/361 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371912582; called by muse, mutect2, varscan2
- OBSCN | c.18646G>A p.V6216M | Missense Mutation (SNP) | VAF 123/277 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs757146288; called by muse, mutect2, varscan2
- OR10H2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 128/306 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs756001079, COSV59945286; called by muse, mutect2, varscan2
- OR2A14 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 97/245 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as rs1481069147, COSV68718411; called by muse, mutect2, varscan2
- OR56B4 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 187/456 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs61743916; called by muse, mutect2, varscan2
- OSGIN2 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 233/549 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs201554027, COSV52412274; called by muse, mutect2, varscan2
- P4HA1 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 180/256 reads (70%) | catalogued as COSV54961447; called by muse, mutect2, varscan2
- PARP3 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 211/519 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs369155045; called by muse, mutect2, varscan2
- PCDH17 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 113/266 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.108); catalogued as COSV64973158; called by muse, mutect2, varscan2
- PCDHB5 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50650806, COSV99169467; called by muse, mutect2, varscan2
- PCDHGA2 | c.1853C>T p.S618L | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.052); catalogued as rs776431934, COSV53946657; called by muse, mutect2, varscan2
- PCLO | c.12884C>T p.P4295L | Missense Mutation (SNP) | VAF 193/441 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760492327; called by muse, mutect2, varscan2
- PCSK5 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 133/258 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100950394; called by muse, mutect2, varscan2
- PDE3B | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 206/500 reads (41%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.987); catalogued as rs913474010; called by muse, varscan2
- PELP1 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 140/334 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs745722648, COSV99342737; called by muse, mutect2, varscan2
- PENK | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 162/378 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201807450, COSV100152256; called by muse, mutect2, varscan2
- PHF1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 118/279 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs571858795; called by muse, mutect2, varscan2
- PHF21A | c.1955dup p.A653Cfs*22 (on ENST00000418153 / NM_001101802.3; = p.A607Cfs*22 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 75/220 reads (34%) | catalogued as rs761575760; called by mutect2, varscan2
- PHF3 | c.3193G>A p.A1065T | Missense Mutation (SNP) | VAF 275/648 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV100012807; called by muse, mutect2, varscan2
- PHIP | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 575/673 reads (85%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as rs1044058522, COSV51502524; called by muse, mutect2, varscan2
- PIBF1 | c.33del p.V12* | Frame Shift Del (DEL) | VAF 211/456 reads (46%) | catalogued as rs925772654; called by mutect2, varscan2
- PIK3R1 | c.1718T>C p.L573P (on ENST00000521381 / NM_181523.3; = p.L303P on NM_181504.4) | Missense Mutation (SNP) | VAF 35/772 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57124674; called by muse, mutect2
- PITPNM3 | c.1083A>G p.S361= | Splice Region (SNP) | VAF 17/325 reads (5%) | catalogued as rs957525636; called by muse, mutect2
- PIWIL4 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 98/259 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs746205490; called by muse, mutect2, varscan2
- PKD1L3 | c.1306A>G p.T436A | Missense Mutation (SNP) | VAF 181/479 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.359); catalogued as rs765978427; called by muse, mutect2, varscan2
- PKHD1L1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 344/804 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs536145343, COSV65750020; called by muse, varscan2
- PKHD1L1 | c.3821C>T p.A1274V | Missense Mutation (SNP) | VAF 173/496 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs202179223, COSV65751623; called by muse, mutect2, varscan2
- PKNOX2 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 192/474 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs781020037, COSV53541095; called by muse, mutect2, varscan2
- PLIN2 | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 176/424 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs145392085; called by mutect2, varscan2
- PLPP7 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 127/290 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs767973643, COSV100953126; called by muse, mutect2
- PLXNA1 | c.4219G>A p.V1407M | Missense Mutation (SNP) | VAF 165/365 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs73196567; called by muse, mutect2, varscan2
- POT1 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 317/674 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as rs1385542313, COSV62928142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPFIBP2 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 236/596 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs753622546; called by muse, mutect2, varscan2
- PRMT7 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 166/415 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773593082, COSV100267412; called by muse, mutect2, varscan2
- PRSS38 | c.729C>T p.G243= | Splice Region (SNP) | VAF 137/364 reads (38%) | catalogued as rs776964607; called by muse, mutect2, varscan2
- PSEN2 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 168/420 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs199808788, COSV100423360; called by muse, mutect2, varscan2
- PTPRN2 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs146528593; called by muse, mutect2
- PYGB | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 183/447 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.372); catalogued as COSV53818172; called by muse, mutect2, varscan2
- R3HDM2 | c.2416C>T p.R806C | Missense Mutation (SNP) | VAF 78/215 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs756247490; called by muse, mutect2, varscan2
- RAB34 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 136/336 reads (40%) | catalogued as rs375545338; called by muse, mutect2, varscan2
- RAD17 | c.608C>T p.A203V (on ENST00000380774 / NM_133339.2; = p.A192V on NM_002873.1) | Missense Mutation (SNP) | VAF 53/572 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs150902866; called by muse, mutect2
- RADIL | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 153/394 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs751170021, COSV68201614; called by muse, mutect2, varscan2
- RAPH1 | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 199/482 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as rs576908552, COSV55590772; called by muse, mutect2, varscan2
- RBM10 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61310218, COSV61310251; called by muse, mutect2
- RBMXL3 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 92/117 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.689); catalogued as rs1050701040, COSV57756350; called by muse, mutect2, varscan2
- RCBTB2 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 279/689 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.217); catalogued as rs771974782, COSV60650035, COSV60650255, COSV60651745; called by muse, mutect2, varscan2
- RCOR1 | c.190G>C p.A64P | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT tolerated, low confidence (0.3); catalogued as COSV51767462, COSV51772689; called by muse, mutect2, varscan2
- RECQL5 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 173/409 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.844); catalogued as COSV53126606; called by muse, mutect2, varscan2
- RELN | c.9748G>A p.D3250N | Missense Mutation (SNP) | VAF 220/512 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV59002460, COSV59007820; called by muse, varscan2
- RGL4 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 143/343 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs764399514, COSV51943965; called by muse, mutect2, varscan2
- RHOBTB2 | c.631C>A p.R211S | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99310881; called by muse, mutect2
- RIMBP2 | c.235del p.L79Wfs*15 | Frame Shift Del (DEL) | VAF 166/390 reads (43%) | catalogued as rs1286661920; called by mutect2, varscan2
- RNF123 | c.2839C>T p.R947C | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs770235692, COSV57540466; called by muse, mutect2, varscan2
- RPA1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 278/663 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758675207; called by muse, mutect2, varscan2
- RPL22L1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 208/529 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as rs957367223, COSV55556727; called by muse, mutect2, varscan2
- RWDD4 | c.204del p.F68Lfs*9 | Frame Shift Del (DEL) | VAF 198/476 reads (42%) | catalogued as rs1325913157; called by mutect2, varscan2
- SACS | c.8176C>G p.L2726V | Missense Mutation (SNP) | VAF 301/733 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV66546735; called by muse, mutect2, varscan2
- SAFB2 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 185/444 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV53042664; called by muse, mutect2, varscan2
- SALL3 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1231719866; called by muse, mutect2, varscan2
- SALL4 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 104/232 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs758122948, COSV53852511; called by muse, mutect2, varscan2
- SAMSN1 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 194/529 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.211); catalogued as COSV53474533; called by muse, mutect2, varscan2
- SBNO2 | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 103/276 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62321107; called by muse, mutect2, varscan2
- SCN4A | c.5404G>A p.G1802R | Missense Mutation (SNP) | VAF 81/263 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs267604988; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / benign / likely benign; called by muse, mutect2, varscan2
- SCN8A | c.5522G>A p.R1841H | Missense Mutation (SNP) | VAF 155/299 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61990629; called by muse, mutect2, varscan2
- SDC3 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs372651371; called by muse, varscan2
- SEC16A | c.4936G>A p.A1646T | Missense Mutation (SNP) | VAF 184/395 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209856165; called by muse, mutect2, varscan2
- SEL1L3 | c.2935G>A p.A979T | Missense Mutation (SNP) | VAF 247/664 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1486381903; called by muse, mutect2, varscan2
- SEMA5A | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 189/409 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1480260294; called by muse, mutect2, varscan2
- SFI1 | c.3032G>A p.R1011H (on ENST00000400288 / NM_001007467.3; = p.R980H on NM_014775.4) | Missense Mutation (SNP) | VAF 195/463 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs371195366, COSV56718094; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 240/649 reads (37%) | catalogued as rs1260834379; called by mutect2, varscan2
- SH2B3 | c.1366G>A p.V456I | Missense Mutation (SNP) | VAF 197/484 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs755803213; called by muse, mutect2, varscan2
- SH3PXD2A | c.1495G>A p.A499T (on ENST00000369774 / NM_001365079.1; = p.A471T on NM_014631.2) | Missense Mutation (SNP) | VAF 226/283 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs747458165; called by muse, mutect2, varscan2
- SHOC1 | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 364/913 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776539346; called by muse, mutect2, varscan2
- SHPRH | c.2381G>A p.R794H | Missense Mutation (SNP) | VAF 222/533 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762906340; called by muse, mutect2, varscan2
- SHROOM3 | c.3649G>A p.G1217R | Missense Mutation (SNP) | VAF 104/285 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs573786896; called by muse, mutect2, varscan2
- SIPA1L1 | c.2345A>G p.D782G | Missense Mutation (SNP) | VAF 244/619 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV62170381; called by muse, mutect2, varscan2
- SIPA1L1 | c.4156C>T p.R1386W | Missense Mutation (SNP) | VAF 252/587 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as rs746610683; called by muse, mutect2, varscan2
- SIRT6 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 66/128 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs558969933; called by muse, mutect2, varscan2
- SLC25A33 | c.22_24del p.K8del | In Frame Del (DEL) | VAF 66/148 reads (45%) | catalogued as rs1402496134; called by mutect2, varscan2
- SLC35G3 | c.169del p.L57Ffs*111 | Frame Shift Del (DEL) | VAF 126/336 reads (38%) | catalogued as rs34114107, COSV99033227; called by mutect2, varscan2
- SLC45A1 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 173/384 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1467070473, COSV57097309; called by muse, mutect2, varscan2
- SLC6A9 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 187/387 reads (48%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.045); catalogued as rs199577336; called by muse, mutect2, varscan2
- SLITRK6 | c.1118A>G p.N373S | Missense Mutation (SNP) | VAF 235/544 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370189442; called by muse, mutect2, varscan2
- SMIM8 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 265/652 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs140990223; called by muse, mutect2, varscan2
- SNPH | c.1309G>A p.V437M | Missense Mutation (SNP) | VAF 102/266 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs755205235, COSV60590142; called by muse, mutect2, varscan2
- SOX30 | c.1465G>A p.V489I | Missense Mutation (SNP) | VAF 201/499 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs367950219, COSV53936650; called by muse, mutect2, varscan2
- SPEM2 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 232/510 reads (45%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1419683294; called by muse, mutect2, varscan2
- SPTA1 | c.3953C>T p.A1318V | Missense Mutation (SNP) | VAF 164/404 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1447159309; called by muse, mutect2, varscan2
- SPTBN1 | c.4294C>T p.R1432W | Missense Mutation (SNP) | VAF 169/459 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.047); catalogued as rs878981910; called by muse, mutect2, varscan2
- SREK1IP1 | c.271del p.R91Gfs*67 | Frame Shift Del (DEL) | VAF 77/144 reads (53%) | catalogued as rs750306056; called by mutect2, varscan2
- STEAP1 | c.936C>G p.C312W | Missense Mutation (SNP) | VAF 197/458 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs201074373; called by muse, mutect2, varscan2
- STXBP6 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 105/258 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1392186683; called by muse, mutect2, varscan2
- SYNPO | c.2435G>A p.R812H (on ENST00000394243 / NM_001166208.2; = p.R568H on NM_007286.6) | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs1264912311; called by muse, mutect2, varscan2
- TACC3 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 91/208 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as rs1469125485; called by muse, mutect2, varscan2
- TAGAP | c.1874C>T p.A625V | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs778745747, COSV57851543; called by muse, mutect2, varscan2
- TARS1 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 257/627 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs200221822; called by muse, mutect2, varscan2
- TBC1D10A | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 158/361 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV53164505; called by muse, mutect2, varscan2
- TBC1D22A | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 114/317 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs759900287; called by muse, mutect2, varscan2
- TBCD | c.2341G>A p.A781T | Missense Mutation (SNP) | VAF 144/345 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs765676218, COSV62808580; called by muse, mutect2, varscan2
- TBX21 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 210/499 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs752687196, COSV99456264; called by muse, mutect2, varscan2
- TCEA2 | c.518G>A p.C173Y | Missense Mutation (SNP) | VAF 209/442 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1003112123, COSV100180771; called by muse, mutect2, varscan2
- TCF3 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 97/258 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370362031; called by muse, mutect2, varscan2
- TDRD6 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 225/496 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs759867243, COSV60176513; called by muse, mutect2, varscan2
- TEAD3 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 130/276 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100132400; called by muse, mutect2, varscan2
- TEKT2 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 153/372 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.435); catalogued as rs561472596; called by muse, mutect2, varscan2
- THUMPD1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 230/534 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768220799, COSV67263339; called by muse, varscan2
- TJP2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 144/355 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs576667891; called by muse, mutect2, varscan2
- TKTL2 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 182/390 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as rs1368882327; called by muse, mutect2, varscan2
- TMEM213 | c.156C>T p.N52= | Splice Region (SNP) | VAF 67/179 reads (37%) | catalogued as rs778307980, COSV59475430; called by muse, mutect2, varscan2
- TNNI3K | c.2269C>T p.R757W | Missense Mutation (SNP) | VAF 279/710 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); catalogued as rs201798397, COSV53947863, COSV53949108; called by muse, mutect2, varscan2
- TNS3 | c.3073G>A p.A1025T | Missense Mutation (SNP) | VAF 144/385 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1333688185, COSV100235097, COSV100235342; called by muse, mutect2, varscan2
- TRIM14 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 136/351 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs772008221; called by muse, mutect2, varscan2
- TRIM22 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 251/609 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV66090254; called by muse, mutect2, varscan2
- TRIM49 | c.344G>A p.C115Y | Missense Mutation (SNP) | VAF 160/786 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV61670691; called by muse, mutect2, varscan2
- TRPV6 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 237/561 reads (42%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as rs771971978; called by muse, mutect2, varscan2
- TSC2 | c.339C>T p.G113= | Splice Region (SNP) | VAF 113/269 reads (42%) | catalogued as rs368451664, CD078583; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- TSKS | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 88/220 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs754948650; called by muse, mutect2, varscan2
- TSPYL5 | c.409del p.R137Afs*27 | Frame Shift Del (DEL) | VAF 143/400 reads (36%) | catalogued as COSV59071699; called by mutect2, varscan2
- TTC39B | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 182/465 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs753437755; called by muse, mutect2, varscan2
- TUBB6 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.194); catalogued as rs202041514; called by muse, mutect2, varscan2
- TULP1 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 119/305 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); catalogued as rs1398566369; called by muse, varscan2
- TYW1B | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 393/908 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781996061, COSV100646494; called by muse, mutect2, varscan2
- UBD | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 115/295 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.184); catalogued as rs370066296, COSV100589851; called by muse, mutect2, varscan2
- UFSP2 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 252/605 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as rs778321208, COSV52990504; called by muse, mutect2, varscan2
- USP20 | c.1807G>A p.V603I | Missense Mutation (SNP) | VAF 151/407 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1424438236, COSV59615648; called by muse, mutect2, varscan2
- USP43 | c.2641C>T p.R881W | Missense Mutation (SNP) | VAF 155/363 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs371537626; called by muse, mutect2, varscan2
- UTRN | c.9876del p.L3293Sfs*23 | Frame Shift Del (DEL) | VAF 141/326 reads (43%) | catalogued as COSV62309105; called by mutect2, varscan2
- VSIG2 | c.297dup p.T100Hfs*11 | Frame Shift Ins (INS) | VAF 89/231 reads (39%) | catalogued as rs766405238; called by mutect2, varscan2
- ZACN | c.544+2T>C p.X182_splice | Splice Site (SNP) | VAF 208/479 reads (43%) | catalogued as rs775416968; called by muse, mutect2, varscan2
- ZBED1 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 254/304 reads (84%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs780897539; called by muse, mutect2, varscan2
- ZBTB48 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 201/457 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs754544102; called by muse, mutect2, varscan2
- ZFYVE9 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 146/416 reads (35%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.003); catalogued as rs528396709; called by muse, mutect2, varscan2
- ZNF169 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 160/428 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369966911; called by muse, mutect2, varscan2
- ZNF300 | c.1137A>C p.K379N | Missense Mutation (SNP) | VAF 205/474 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51032058; called by mutect2, varscan2
- ZNF483 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 205/443 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146828490; called by muse, mutect2, varscan2
- ZNF581 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 124/320 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs963947913, COSV54401779; called by muse, mutect2, varscan2
- ZNF831 | c.1822G>A p.G608S | Missense Mutation (SNP) | VAF 136/299 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs778522755; called by muse, mutect2, varscan2
- ZNF875 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 177/440 reads (40%) | catalogued as rs374853630, COSV100183341; called by muse, mutect2, varscan2
- ZSCAN10 | c.1321C>T p.R441W (on ENST00000252463; = p.R496W on NM_032805.3) | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs569119394; called by muse, mutect2, varscan2
- ABCA6 | c.14A>G p.Q5R | Missense Mutation (SNP) | VAF 213/509 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCG5 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 305/666 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ABI3BP | c.1000A>G p.T334A | Missense Mutation (SNP) | VAF 141/330 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- AC004593.2 | c.647C>A p.A216D | Missense Mutation (SNP) | VAF 158/439 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- ACP7 | c.1023G>A p.W341* | Nonsense Mutation (SNP) | VAF 21/454 reads (5%) | called by muse, mutect2
- ACTL7B | c.126G>T p.K42N | Missense Mutation (SNP) | VAF 123/313 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ADAM10 | c.1039del p.S347Vfs*12 | Frame Shift Del (DEL) | VAF 147/210 reads (70%) | called by mutect2, varscan2
- ANG | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 192/416 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANGPTL6 | c.1090T>G p.F364V | Missense Mutation (SNP) | VAF 105/239 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD12 | c.6004-1G>A p.X2002_splice | Splice Site (SNP) | VAF 102/216 reads (47%) | called by muse, mutect2, varscan2
- ANO6 | c.1903C>T p.R635* | Nonsense Mutation (SNP) | VAF 174/450 reads (39%) | called by muse, mutect2, varscan2
- AQP1 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 133/350 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ARHGAP24 | c.1799A>G p.D600G (on ENST00000395184 / NM_001025616.3; = p.D507G on NM_031305.3) | Missense Mutation (SNP) | VAF 230/533 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ASPHD1 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 130/319 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- ATP11C | c.691T>A p.Y231N | Missense Mutation (SNP) | VAF 172/218 reads (79%) | SIFT tolerated (0.13); PolyPhen benign (0.05); called by mutect2, varscan2
- ATP1A2 | c.2137G>A p.G713S | Missense Mutation (SNP) | VAF 219/523 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP5F1C | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 191/422 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- ATRX | c.3904del p.R1302Efs*44 | Frame Shift Del (DEL) | VAF 282/655 reads (43%) | called by mutect2, varscan2
- BABAM1 | c.219G>T p.W73C | Missense Mutation (SNP) | VAF 138/328 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- BBS12 | c.4G>A p.V2M | Missense Mutation (SNP) | VAF 234/585 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BMI1 | c.958T>G p.S320A | Missense Mutation (SNP) | VAF 207/461 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BTBD8 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 86/282 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C12orf40 | c.101A>T p.K34I | Missense Mutation (SNP) | VAF 175/468 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CALCOCO2 | c.1337T>C p.L446P | Missense Mutation (SNP) | VAF 196/498 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CAMSAP1 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 231/537 reads (43%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CBWD1 | c.300G>A p.W100* | Nonsense Mutation (SNP) | VAF 106/442 reads (24%) | called by muse, mutect2, varscan2
- CDADC1 | c.284dup p.N95Kfs*11 | Frame Shift Ins (INS) | VAF 168/364 reads (46%) | called by mutect2, varscan2
- CEACAM16 | c.58del p.A20Pfs*51 | Frame Shift Del (DEL) | VAF 96/194 reads (49%) | called by mutect2, varscan2
- CENPE | c.5986del p.I1996Lfs*7 | Frame Shift Del (DEL) | VAF 298/751 reads (40%) | called by mutect2, varscan2
- CENPF | c.7830dup p.V2611Sfs*10 | Frame Shift Ins (INS) | VAF 120/300 reads (40%) | called by mutect2, varscan2
- CFAP44 | c.5267T>C p.L1756P | Missense Mutation (SNP) | VAF 26/888 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CFAP65 | c.2584dup p.Q862Pfs*58 | Frame Shift Ins (INS) | VAF 176/397 reads (44%) | called by mutect2, varscan2
- CHUK | c.810A>C p.E270D | Missense Mutation (SNP) | VAF 172/232 reads (74%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CLIC1 | c.677A>C p.D226A | Missense Mutation (SNP) | VAF 18/386 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- COG6 | c.1237del p.I413Yfs*6 | Frame Shift Del (DEL) | VAF 264/622 reads (42%) | called by mutect2, varscan2
- COL12A1 | c.3185A>G p.D1062G | Missense Mutation (SNP) | VAF 222/533 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- COL18A1 | c.2891del p.P964Qfs*175 (on ENST00000359759 / NM_130444.3; = p.P729Qfs*175 on NM_030582.4) | Frame Shift Del (DEL) | VAF 132/308 reads (43%) | called by mutect2, varscan2
- COL3A1 | c.3044A>C p.N1015T | Missense Mutation (SNP) | VAF 172/438 reads (39%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- CORO6 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 152/375 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- CPNE3 | c.1024T>G p.F342V | Missense Mutation (SNP) | VAF 173/365 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CRB2 | c.2941G>A p.A981T | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CYSLTR2 | c.698T>C p.V233A | Missense Mutation (SNP) | VAF 215/494 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYTH1 | c.961C>A p.P321T | Missense Mutation (SNP) | VAF 241/574 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); called by mutect2, varscan2
- DACH1 | c.499del p.L167Sfs*27 | Frame Shift Del (DEL) | VAF 47/126 reads (37%) | called by mutect2, varscan2
- DDX42 | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 151/415 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAH10 | c.13016_13017del p.F4339Yfs*6 (on ENST00000409039; = p.F4278Yfs*6 on NM_207437.3) | Frame Shift Del (DEL) | VAF 223/558 reads (40%) | called by mutect2, varscan2
- DNAH7 | c.2634C>A p.D878E | Missense Mutation (SNP) | VAF 206/546 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- DROSHA | c.1984T>C p.W662R | Missense Mutation (SNP) | VAF 206/458 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- EBF1 | c.1659A>C p.K553N | Missense Mutation (SNP) | VAF 20/535 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EFCAB12 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 218/524 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENDOD1 | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 246/578 reads (43%) | SIFT tolerated (0.98); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EPB41L1 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 157/378 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ERI2 | c.944del p.N315Tfs*3 | Frame Shift Del (DEL) | VAF 230/576 reads (40%) | called by mutect2, varscan2
- FAM114A1 | c.1431del p.K477Nfs*10 | Frame Shift Del (DEL) | VAF 178/441 reads (40%) | called by mutect2, varscan2
- FAM47C | c.658T>A p.S220T | Missense Mutation (SNP) | VAF 148/180 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0.188); called by mutect2, varscan2
- FFAR3 | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 163/576 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FIP1L1 | c.364A>C p.I122L | Missense Mutation (SNP) | VAF 136/374 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- FLG2 | c.4763del p.G1588Afs*37 | Frame Shift Del (DEL) | VAF 124/341 reads (36%) | called by mutect2, varscan2
- FOXF2 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRAS1 | c.6465C>T p.G2155= | Splice Region (SNP) | VAF 104/220 reads (47%) | called by muse, mutect2, varscan2
- GBP1 | c.1043A>G p.E348G | Missense Mutation (SNP) | VAF 250/507 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GIMAP6 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 108/184 reads (59%) | SIFT tolerated (0.51); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GLYATL2 | c.113A>C p.N38T | Missense Mutation (SNP) | VAF 222/566 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- GNPNAT1 | c.345+6T>C | Splice Region (SNP) | VAF 22/281 reads (8%) | called by muse, mutect2
- H4C9 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 232/517 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- HCN1 | c.722A>G p.K241R | Missense Mutation (SNP) | VAF 262/634 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- HCN3 | c.2126del p.G709Afs*75 | Frame Shift Del (DEL) | VAF 76/187 reads (41%) | called by mutect2, varscan2
- HIVEP2 | c.4348C>A p.L1450I | Missense Mutation (SNP) | VAF 18/534 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.433); called by muse, mutect2
- HR | c.2512del p.R838Gfs*64 | Frame Shift Del (DEL) | VAF 78/198 reads (39%) | called by mutect2, varscan2
- HRNR | c.2464T>G p.S822A | Missense Mutation (SNP) | VAF 123/289 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- HSD17B6 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 196/463 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- HUS1B | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 154/418 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.316); called by muse, varscan2
- HUS1B | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 190/452 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, varscan2
- IDH3G | c.81+2T>C p.X27_splice | Splice Site (SNP) | VAF 108/123 reads (88%) | called by muse, mutect2, varscan2
- ILF3 | c.1201del p.Q401Rfs*3 | Frame Shift Del (DEL) | VAF 124/275 reads (45%) | called by mutect2, varscan2
- IRAG2 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 214/561 reads (38%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ITGAM | c.3155T>C p.L1052P (on ENST00000648685 / NM_001145808.2; = p.L1051P on NM_000632.4) | Missense Mutation (SNP) | VAF 30/516 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KBTBD11 | c.1642A>G p.T548A | Missense Mutation (SNP) | VAF 128/314 reads (41%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA0319L | c.1442A>G p.D481G | Missense Mutation (SNP) | VAF 133/279 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL4 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 199/461 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- KNDC1 | c.3505T>C p.S1169P | Missense Mutation (SNP) | VAF 143/196 reads (73%) | SIFT tolerated (0.38); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LCT | c.3720G>A p.W1240* | Nonsense Mutation (SNP) | VAF 189/468 reads (40%) | called by muse, mutect2, varscan2
- LDLRAD4 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 164/431 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LIPT2 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 197/472 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- LONRF2 | c.2105T>C p.I702T | Missense Mutation (SNP) | VAF 192/438 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- LRCH4 | c.1279del p.A427Pfs*8 | Frame Shift Del (DEL) | VAF 96/300 reads (32%) | called by mutect2, varscan2
- LRP2 | c.9068A>T p.D3023V | Missense Mutation (SNP) | VAF 281/629 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTA4H | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 33/514 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2
- MAGI1 | c.2697del p.F899Lfs*26 (on ENST00000402939 / NM_001033057.2; = p.F927Lfs*26 on NM_004742.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 170/368 reads (46%) | called by mutect2, varscan2
- MANEAL | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 76/149 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- MC3R | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 217/480 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- MGAM2 | c.3823G>A p.A1275T | Missense Mutation (SNP) | VAF 243/580 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MS4A14 | c.1916T>C p.L639P | Missense Mutation (SNP) | VAF 222/506 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, varscan2
- MTCL1 | c.2080del p.L694Cfs*5 (on ENST00000306329 / NM_001378206.1; = p.L334Cfs*5 on NM_015210.4) | Frame Shift Del (DEL) | VAF 54/144 reads (38%) | called by mutect2, varscan2
- MUC15 | c.909T>A p.N303K | Missense Mutation (SNP) | VAF 321/722 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MUC5B | c.15127C>T p.P5043S | Missense Mutation (SNP) | VAF 214/488 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- MXRA5 | c.4442A>G p.H1481R | Missense Mutation (SNP) | VAF 177/244 reads (73%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBEAL2 | c.4048T>C p.S1350P | Missense Mutation (SNP) | VAF 175/489 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NCKAP5L | c.788del p.G263Vfs*64 | Frame Shift Del (DEL) | VAF 122/276 reads (44%) | called by mutect2, varscan2
- NCOA4 | c.224A>G p.D75G | Missense Mutation (SNP) | VAF 424/744 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NFRKB | c.2512del p.V838Ffs*10 (on ENST00000446488 / NM_001143835.2; = p.V863Ffs*10 on NM_006165.3) | Frame Shift Del (DEL) | VAF 176/382 reads (46%) | called by mutect2, varscan2
- NID1 | c.2576C>T p.A859V | Missense Mutation (SNP) | VAF 196/467 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NIPAL2 | c.955T>C p.S319P | Missense Mutation (SNP) | VAF 161/384 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NKRF | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 243/317 reads (77%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- NLRC5 | c.5143T>C p.S1715P | Missense Mutation (SNP) | VAF 118/291 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- NOX3 | c.1351T>C p.W451R | Missense Mutation (SNP) | VAF 203/564 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- NPHP4 | c.3148del p.Q1050Sfs*33 | Frame Shift Del (DEL) | VAF 148/358 reads (41%) | called by mutect2, varscan2
- NT5DC2 | c.121+8C>T | Splice Region (SNP) | VAF 144/326 reads (44%) | called by mutect2, varscan2
- OR13C8 | c.502T>C p.F168L | Missense Mutation (SNP) | VAF 250/613 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- OR2B6 | c.718A>G p.T240A | Missense Mutation (SNP) | VAF 153/380 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- OR4K5 | c.299A>C p.Q100P | Missense Mutation (SNP) | VAF 194/433 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR56B4 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 156/395 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR5M1 | c.4T>G p.F2V | Missense Mutation (SNP) | VAF 90/204 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5P2 | c.59T>C p.L20S | Missense Mutation (SNP) | VAF 260/588 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- P4HB | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 226/559 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PAPPA | c.3698A>G p.Y1233C | Missense Mutation (SNP) | VAF 212/511 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.72); called by muse, varscan2
- PCDH15 | c.3788del p.K1263Rfs*2 | Frame Shift Del (DEL) | VAF 112/416 reads (27%) | called by mutect2, varscan2
- PCDHA5 | c.1297T>G p.S433A | Missense Mutation (SNP) | VAF 216/522 reads (41%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.098); called by mutect2, varscan2
- PCDHGA4 | c.2507A>G p.N836S | Missense Mutation (SNP) | VAF 144/360 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCLO | c.7232del p.P2411Lfs*33 | Frame Shift Del (DEL) | VAF 36/74 reads (49%) | called by mutect2, varscan2
- PDE10A | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 150/405 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- PDZRN4 | c.843+2T>C p.X281_splice | Splice Site (SNP) | VAF 169/436 reads (39%) | called by muse, mutect2
- PEPD | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 258/609 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHF10 | c.826T>C p.Y276H | Missense Mutation (SNP) | VAF 20/572 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- PLCB4 | c.1372dup p.I458Nfs*11 | Frame Shift Ins (INS) | VAF 276/602 reads (46%) | called by mutect2, varscan2
- PLEKHH3 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 188/422 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, varscan2
- PMCH | c.227A>C p.E76A | Missense Mutation (SNP) | VAF 318/758 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2
- PNMA8B | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 90/226 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.264); called by muse, mutect2
- PNPLA6 | c.3841G>A p.A1281T (on ENST00000414982 / NM_001166111.2; = p.A1233T on NM_006702.5) | Missense Mutation (SNP) | VAF 123/254 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPIP5K2 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 136/393 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRPS1L1 | c.215T>C p.I72T | Missense Mutation (SNP) | VAF 270/661 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PRRC2A | c.2219dup p.L741Sfs*30 | Frame Shift Ins (INS) | VAF 93/253 reads (37%) | called by mutect2, varscan2
- PTEN | c.815_816del p.H272Lfs*25 | Frame Shift Del (DEL) | VAF 96/126 reads (76%) | called by mutect2, varscan2
- PTPRT | c.4214A>G p.D1405G | Missense Mutation (SNP) | VAF 233/599 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB6B | c.404A>G p.Q135R | Missense Mutation (SNP) | VAF 22/592 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.218); called by muse, mutect2
- RALGAPA1 | c.309G>T p.W103C | Missense Mutation (SNP) | VAF 143/423 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- RASGRP1 | c.1012_1014del p.D338del | In Frame Del (DEL) | VAF 201/273 reads (74%) | called by mutect2, varscan2
- RAVER1 | c.1261+5C>T | Splice Region (SNP) | VAF 65/192 reads (34%) | called by muse, mutect2, varscan2
- RBM19 | c.542A>T p.E181V | Missense Mutation (SNP) | VAF 199/444 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- RELN | c.7262G>A p.C2421Y | Missense Mutation (SNP) | VAF 219/515 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RNF10 | c.985T>C p.Y329H | Missense Mutation (SNP) | VAF 154/362 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- RPS6KA2 | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 152/365 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCLT1 | c.1269del p.A424Qfs*6 | Frame Shift Del (DEL) | VAF 225/494 reads (46%) | called by mutect2, varscan2
- SCYL3 | c.1853G>A p.S618N (on ENST00000367770; = p.S564N on NM_020423.7) | Missense Mutation (SNP) | VAF 198/467 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEC22C | c.18dup p.A7Cfs*17 | Frame Shift Ins (INS) | VAF 152/366 reads (42%) | called by mutect2, varscan2
- SIGIRR | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 116/318 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SIGLEC16 | c.865del p.Q289Rfs*? | Frame Shift Del (DEL) | VAF 62/143 reads (43%) | called by mutect2, varscan2
- SLC17A8 | c.1748G>T p.R583I | Missense Mutation (SNP) | VAF 111/291 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SLC1A1 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 198/449 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC22A25 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 211/560 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- SMARCA1 | c.2666G>A p.G889D | Missense Mutation (SNP) | VAF 343/435 reads (79%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SMG1 | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 149/398 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SMTNL1 | c.1071dup p.Y358Ifs*29 (on ENST00000399154; = p.Y395Ifs*29 on NM_001105565.2) | Frame Shift Ins (INS) | VAF 165/451 reads (37%) | called by mutect2, varscan2
- SPAG17 | c.2291T>C p.V764A | Missense Mutation (SNP) | VAF 217/491 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- SPIRE1 | c.134T>C p.I45T | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- SPTA1 | c.872A>G p.D291G | Missense Mutation (SNP) | VAF 263/626 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- STEAP4 | c.141del p.F47Lfs*19 | Frame Shift Del (DEL) | VAF 248/607 reads (41%) | called by mutect2, varscan2
- STS | c.515T>C p.V172A | Missense Mutation (SNP) | VAF 212/263 reads (81%) | SIFT tolerated (0.48); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- STXBP5 | c.2428T>C p.S810P (on ENST00000321680 / NM_001127715.2; = p.S774P on NM_139244.4) | Missense Mutation (SNP) | VAF 171/417 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2
- SUCNR1 | c.581T>G p.L194W | Missense Mutation (SNP) | VAF 142/365 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- SUN5 | c.461A>G p.E154G | Missense Mutation (SNP) | VAF 244/530 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TANC1 | c.2772del p.N925Tfs*2 | Frame Shift Del (DEL) | VAF 164/436 reads (38%) | called by mutect2, varscan2
- TAP2 | c.554A>C p.D185A | Missense Mutation (SNP) | VAF 142/378 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- TBCD | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 147/347 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- TET3 | c.3226G>A p.A1076T | Missense Mutation (SNP) | VAF 143/341 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFCP2 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 180/477 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- TFR2 | c.1546A>G p.K516E | Missense Mutation (SNP) | VAF 33/584 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.061); called by muse, mutect2
- TIA1 | c.104del p.N35Tfs*4 | Frame Shift Del (DEL) | VAF 174/418 reads (42%) | called by mutect2, varscan2
- TNFSF12 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 16/494 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- TOX4 | c.1862A>G p.K621R | Missense Mutation (SNP) | VAF 142/372 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TP63 | c.1730A>C p.E577A | Missense Mutation (SNP) | VAF 23/403 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); called by muse, mutect2
- TRPM2 | c.4208A>T p.K1403M | Missense Mutation (SNP) | VAF 120/249 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TRPM2 | c.4331C>T p.A1444V | Missense Mutation (SNP) | VAF 196/517 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TSHZ2 | c.1544A>G p.D515G | Missense Mutation (SNP) | VAF 149/337 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTC26 | c.167A>G p.E56G | Missense Mutation (SNP) | VAF 232/524 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TTLL6 | c.1767C>G p.I589M (on ENST00000393382 / NM_001130918.3; = p.I282M on NM_173623.3) | Missense Mutation (SNP) | VAF 194/500 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- TTN | c.93176-5del | Splice Region (DEL) | VAF 94/201 reads (47%) | called by mutect2, varscan2
- UBN2 | c.178dup p.R60Pfs*58 | Frame Shift Ins (INS) | VAF 21/77 reads (27%) | called by mutect2, varscan2
- UBXN11 | c.1055del p.G352Afs*61 (on ENST00000374221 / NM_183008.2; = p.G319Afs*61 on NM_145345.2) | Frame Shift Del (DEL) | VAF 136/315 reads (43%) | called by mutect2, varscan2
- UGT2B4 | c.1330A>G p.K444E | Missense Mutation (SNP) | VAF 217/477 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- UNC13C | c.6287A>C p.D2096A | Missense Mutation (SNP) | VAF 207/276 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UTS2B | c.129del p.K43Nfs*13 | Frame Shift Del (DEL) | VAF 200/440 reads (45%) | called by mutect2, varscan2
- WDR48 | c.314A>G p.H105R | Missense Mutation (SNP) | VAF 280/687 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- WDR72 | c.1607A>C p.D536A | Missense Mutation (SNP) | VAF 160/219 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- WIZ | c.3031G>A p.A1011T (on ENST00000673675 / NM_001371589.1; = p.A188T on NM_001330395.4) | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ZKSCAN5 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 200/505 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ZMYM3 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 187/423 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF365 | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 373/590 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ZNF513 | c.423del p.L143Cfs*23 | Frame Shift Del (DEL) | VAF 42/134 reads (31%) | called by mutect2, varscan2
- ZNF616 | c.1937T>C p.V646A | Missense Mutation (SNP) | VAF 231/531 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF7 | c.1607T>C p.M536T | Missense Mutation (SNP) | VAF 165/405 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- ZNF749 | c.70A>G p.I24V | Missense Mutation (SNP) | VAF 217/524 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF83 | c.1139A>G p.K380R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCB4 | c.3690C>T p.G1230= (on ENST00000265723 / NM_018849.3; = p.G1223= on NM_000443.4) | Silent (SNP) | VAF 191/534 reads (36%) | called by muse, mutect2, varscan2
- ABCC3 | c.2382C>T p.I794= | Silent (SNP) | VAF 250/591 reads (42%) | catalogued as rs149910028; ClinVar: likely benign; called by muse, mutect2, varscan2
- ABCG2 | c.462T>C p.N154= | Silent (SNP) | VAF 354/809 reads (44%) | called by muse, mutect2
- ACOT7 | c.366G>A p.A122= (on ENST00000377855 / NM_181864.3; = p.A112= on NM_007274.4) | Silent (SNP) | VAF 216/577 reads (37%) | catalogued as rs760397210, COSV64114904; called by muse, mutect2, varscan2
- ACTL7B | c.636C>T p.G212= | Silent (SNP) | VAF 105/291 reads (36%) | catalogued as rs756015624, COSV65926810; called by muse, mutect2, varscan2
- ADAMTS8 | c.1122C>T p.D374= | Silent (SNP) | VAF 149/376 reads (40%) | catalogued as rs572124856; called by muse, mutect2, varscan2
- ADAT3 | c.732C>T p.C244= | Silent (SNP) | VAF 90/163 reads (55%) | catalogued as rs866932530, COSV60191683; called by muse, mutect2, varscan2
- ADGRV1 | c.15009C>T p.G5003= | Silent (SNP) | VAF 231/604 reads (38%) | catalogued as rs375195936, COSV67979770; called by muse, mutect2, varscan2
- ALDOB | c.390C>T p.G130= | Silent (SNP) | VAF 171/473 reads (36%) | called by muse, mutect2, varscan2
- ALK | c.2265C>T p.H755= | Silent (SNP) | VAF 243/596 reads (41%) | catalogued as rs770603023, COSV66565155; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANO8 | c.3639G>A p.A1213= | Silent (SNP) | VAF 67/161 reads (42%) | called by muse, mutect2, varscan2
- AOC2 | c.1500C>T p.G500= | Silent (SNP) | VAF 116/268 reads (43%) | called by muse, mutect2, varscan2
- AP5Z1 | c.480C>T p.V160= | Silent (SNP) | VAF 211/491 reads (43%) | catalogued as rs1442727091; called by muse, mutect2, varscan2
- AR | c.1575C>T p.G525= | Silent (SNP) | VAF 147/350 reads (42%) | called by muse, mutect2, varscan2
- ARID1A | c.129A>G p.A43= | Silent (SNP) | VAF 85/177 reads (48%) | catalogued as rs1158398856; called by muse, mutect2, varscan2
- C15orf40 | c.186C>T p.C62= | Silent (SNP) | VAF 16/320 reads (5%) | catalogued as rs1264761052, COSV58449250; called by muse, mutect2
- CACNA1A | c.3273C>T p.H1091= | Silent (SNP) | VAF 112/235 reads (48%) | catalogued as rs776799566; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA1B | c.3687C>T p.G1229= | Silent (SNP) | VAF 203/466 reads (44%) | catalogued as rs199707607, COSV53140330; called by muse, mutect2, varscan2
- CACNA1I | c.5385G>T p.S1795= | Silent (SNP) | VAF 87/229 reads (38%) | called by muse, mutect2, varscan2
- CCN1 | c.378C>T p.G126= | Silent (SNP) | VAF 150/372 reads (40%) | catalogued as rs1178040634, COSV71704305; called by muse, mutect2, varscan2
- CCNE1 | c.60C>T p.G20= | Silent (SNP) | VAF 94/243 reads (39%) | catalogued as rs755757691; called by muse, mutect2, varscan2
- CCSER2 | c.576C>A p.S192= | Silent (SNP) | VAF 22/526 reads (4%) | called by muse, mutect2
- CDH4 | c.1434G>A p.A478= | Silent (SNP) | VAF 178/459 reads (39%) | catalogued as rs543161849, COSV64672653; called by muse, mutect2, varscan2
- CDK13 | c.2913G>A p.A971= | Silent (SNP) | VAF 146/343 reads (43%) | catalogued as rs149612730; called by muse, varscan2
- CERS5 | c.912C>T p.I304= | Silent (SNP) | VAF 206/478 reads (43%) | catalogued as rs752285189, COSV58188660; called by muse, mutect2, varscan2
- CHST12 | c.1188C>T p.Y396= | Silent (SNP) | VAF 122/314 reads (39%) | catalogued as rs781483816, COSV51673977; called by muse, mutect2, varscan2
- CLPB | c.1062C>T p.I354= | Silent (SNP) | VAF 233/505 reads (46%) | catalogued as rs200459120; called by muse, mutect2, varscan2
- COL12A1 | c.6429T>C p.V2143= | Silent (SNP) | VAF 295/663 reads (44%) | called by muse, mutect2, varscan2
- COL17A1 | c.1317C>T p.G439= | Silent (SNP) | VAF 29/259 reads (11%) | catalogued as rs200949191; ClinVar: likely benign; called by muse, mutect2, varscan2
- CR589904.2 | c.39C>T p.C13= | Silent (SNP) | VAF 244/547 reads (45%) | called by muse, mutect2, varscan2
- CRACD | c.1335C>T p.S445= | Silent (SNP) | VAF 182/400 reads (46%) | catalogued as rs973776811, COSV51720370; called by muse, mutect2, varscan2
- DLK1 | c.663C>T p.G221= | Silent (SNP) | VAF 28/458 reads (6%) | called by muse, mutect2
- DLX3 | c.840G>A p.P280= | Silent (SNP) | VAF 130/342 reads (38%) | catalogued as rs748768238, COSV101460563; called by muse, mutect2, varscan2
- DOCK11 | c.2394C>T p.N798= | Silent (SNP) | VAF 187/243 reads (77%) | catalogued as rs142680785; called by muse, mutect2, varscan2
- DOK6 | c.831C>T p.S277= | Silent (SNP) | VAF 189/444 reads (43%) | called by muse, mutect2, varscan2
- DUSP4 | c.252G>A p.E84= | Silent (SNP) | VAF 146/358 reads (41%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.10083C>T p.D3361= | Silent (SNP) | VAF 139/365 reads (38%) | catalogued as rs772665813, COSV64137424; ClinVar: likely benign; called by muse, mutect2, varscan2
- DZIP1 | c.462C>T p.C154= | Silent (SNP) | VAF 149/376 reads (40%) | catalogued as rs148665107; called by muse, mutect2, varscan2
- F7 | c.1005C>T p.F335= | Silent (SNP) | VAF 146/357 reads (41%) | catalogued as rs368893306; called by muse, mutect2, varscan2
- FAM110A | c.435G>A p.P145= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as COSV99856780; called by muse, mutect2, varscan2
- FAM168B | c.201C>T p.S67= | Silent (SNP) | VAF 148/338 reads (44%) | catalogued as rs989120559; called by muse, mutect2, varscan2
- FAT1 | c.10932G>A p.A3644= | Silent (SNP) | VAF 282/695 reads (41%) | catalogued as rs145300656; called by muse, mutect2, varscan2
- FGB | c.1224T>C p.Y408= | Silent (SNP) | VAF 195/436 reads (45%) | called by muse, mutect2, varscan2
- FGF17 | c.438C>T p.H146= | Silent (SNP) | VAF 17/484 reads (4%) | catalogued as rs1294022533, COSV63925371; called by muse, mutect2
- FIGNL2 | c.1059G>A p.P353= | Silent (SNP) | VAF 85/182 reads (47%) | catalogued as rs753941679; called by muse, mutect2, varscan2
- FRY | c.2068C>T p.L690= | Silent (SNP) | VAF 188/474 reads (40%) | catalogued as COSV66580105; called by muse, mutect2, varscan2
- FSIP2 | c.2793C>T p.T931= | Silent (SNP) | VAF 260/683 reads (38%) | catalogued as rs777841945; called by muse, mutect2, varscan2
- GLI2 | c.4458G>A p.Q1486= (on ENST00000361492 / NM_001374353.1; = p.Q1503= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 172/405 reads (42%) | called by muse, mutect2, varscan2
- GLIS3 | c.933G>A p.A311= | Silent (SNP) | VAF 102/245 reads (42%) | catalogued as rs759081727, COSV60934140; called by muse, mutect2, varscan2
- GPR149 | c.444C>T p.G148= | Silent (SNP) | VAF 96/188 reads (51%) | called by muse, mutect2, varscan2
- GTF2IRD2 | c.2451C>T p.S817= | Silent (SNP) | VAF 151/364 reads (41%) | catalogued as rs1316216036, COSV63100343; called by muse, mutect2, varscan2
- GUCY2D | c.2601G>A p.T867= | Silent (SNP) | VAF 179/424 reads (42%) | catalogued as rs760202269, COSV54695866; called by muse, mutect2, varscan2
- GZMB | c.564C>T p.C188= | Silent (SNP) | VAF 116/294 reads (39%) | catalogued as rs149659869, COSV53542628; called by muse, mutect2, varscan2
- HAX1 | c.591C>T p.G197= | Silent (SNP) | VAF 175/455 reads (38%) | called by muse, mutect2, varscan2
- HCN2 | c.1863C>T p.S621= | Silent (SNP) | VAF 147/318 reads (46%) | catalogued as rs139625086; called by muse, mutect2, varscan2
- HIVEP1 | c.3075G>A p.T1025= | Silent (SNP) | VAF 169/424 reads (40%) | catalogued as rs567891397, COSV65100654; called by muse, mutect2, varscan2
- HMCN2 | c.4167C>T p.G1389= | Silent (SNP) | VAF 183/435 reads (42%) | catalogued as rs1337911748; called by muse, mutect2, varscan2
- HMCN2 | c.9609C>T p.C3203= | Silent (SNP) | VAF 75/202 reads (37%) | catalogued as rs746126221; called by muse, mutect2, varscan2
- HPDL | c.261C>T p.D87= | Silent (SNP) | VAF 113/302 reads (37%) | catalogued as rs779527069; called by muse, mutect2, varscan2
- HSPG2 | c.5364C>T p.D1788= | Silent (SNP) | VAF 192/448 reads (43%) | catalogued as rs763046851; called by muse, mutect2, varscan2
- IL1RL1 | c.483G>A p.A161= | Silent (SNP) | VAF 188/470 reads (40%) | catalogued as rs142878092; called by muse, mutect2, varscan2
- IL3RA | c.894C>T p.G298= | Silent (SNP) | VAF 116/167 reads (69%) | catalogued as rs145602140, COSV100452216; called by muse, mutect2, varscan2
- ILDR1 | c.1527G>A p.P509= (on ENST00000344209 / NM_001199799.2; = p.P465= on NM_175924.4) | Silent (SNP) | VAF 266/698 reads (38%) | catalogued as rs149884253; called by muse, mutect2
- ITGB2 | c.546G>A p.T182= | Silent (SNP) | VAF 234/501 reads (47%) | catalogued as rs775424893, COSV56610048; called by muse, mutect2, varscan2
- ITSN1 | c.1737G>A p.R579= | Silent (SNP) | VAF 244/612 reads (40%) | called by muse, mutect2, varscan2
- JAK1 | c.2370C>T p.G790= | Silent (SNP) | VAF 331/762 reads (43%) | catalogued as rs754720992, COSV61091935; called by muse, mutect2, varscan2
- KLF4 | c.432G>A p.A144= | Silent (SNP) | VAF 134/277 reads (48%) | catalogued as rs1242066445; called by muse, mutect2, varscan2
- LBR | c.1053G>A p.A351= | Silent (SNP) | VAF 188/448 reads (42%) | catalogued as rs376668971; called by muse, mutect2, varscan2
- MARCO | c.276G>A p.P92= | Silent (SNP) | VAF 128/335 reads (38%) | catalogued as rs750963747, COSV100503060; called by muse, mutect2, varscan2
- MFSD1 | c.450C>T p.G150= | Silent (SNP) | VAF 100/336 reads (30%) | catalogued as rs750982631, COSV51838932; called by muse, mutect2, varscan2
- MIB1 | c.1425A>G p.G475= | Silent (SNP) | VAF 220/557 reads (39%) | called by muse, mutect2, varscan2
- MLLT1 | c.702C>T p.G234= | Silent (SNP) | VAF 87/218 reads (40%) | catalogued as rs751164053, COSV99398366; called by muse, mutect2, varscan2
- MMP8 | c.165C>T p.G55= | Silent (SNP) | VAF 290/736 reads (39%) | called by muse, varscan2
- MRC1 | c.1953C>T p.G651= | Silent (SNP) | VAF 156/448 reads (35%) | catalogued as rs945635224; called by muse, mutect2, varscan2
- MRM2 | c.468G>A p.A156= | Silent (SNP) | VAF 133/367 reads (36%) | catalogued as rs779182551, COSV54248380, COSV54248433; called by muse, mutect2, varscan2
- MUC12 | c.5187G>A p.T1729= (on ENST00000379442; = p.T1586= on NM_001164462.1) | Silent (SNP) | VAF 46/384 reads (12%) | catalogued as rs568332699; called by muse, varscan2
- MUC6 | c.3285C>T p.G1095= | Silent (SNP) | VAF 109/245 reads (44%) | catalogued as rs773526436; called by muse, mutect2, varscan2
- NDEL1 | c.996G>A p.S332= | Silent (SNP) | VAF 184/428 reads (43%) | catalogued as rs777837051; called by muse, varscan2
- NDUFV1 | c.927C>T p.G309= | Silent (SNP) | VAF 141/341 reads (41%) | catalogued as rs145999490; called by muse, mutect2, varscan2
- OBSCN | c.18042G>A p.P6014= | Silent (SNP) | VAF 80/197 reads (41%) | catalogued as rs377026703; called by muse, mutect2, varscan2
- OPN1LW | c.309C>T p.T103= | Silent (SNP) | VAF 242/310 reads (78%) | catalogued as rs782058799, COSV64064242; called by muse, mutect2, varscan2
- OR10A2 | c.891C>A p.A297= | Silent (SNP) | VAF 126/288 reads (44%) | called by muse, mutect2, varscan2
- OR4C13 | c.522C>T p.H174= | Silent (SNP) | VAF 158/410 reads (39%) | called by muse, mutect2, varscan2
- OR7D4 | c.819C>T p.T273= | Silent (SNP) | VAF 140/256 reads (55%) | catalogued as rs141567228, COSV100432654; called by muse, mutect2, varscan2
- PABPC3 | c.267T>C p.R89= | Silent (SNP) | VAF 241/606 reads (40%) | called by muse, varscan2
- PAFAH1B1 | c.444A>G p.G148= | Silent (SNP) | VAF 221/600 reads (37%) | called by muse, mutect2, varscan2
- PCDHGA11 | c.354C>T p.Y118= | Silent (SNP) | VAF 98/257 reads (38%) | catalogued as COSV53995111; called by muse, mutect2, varscan2
- PCDHGA3 | c.2226C>T p.G742= | Silent (SNP) | VAF 215/537 reads (40%) | catalogued as rs764310422, COSV53904532; called by muse, mutect2, varscan2
- PDPN | c.120C>T p.G40= (on ENST00000621990; = p.G116= on NM_006474.4) | Silent (SNP) | VAF 267/667 reads (40%) | catalogued as rs759482997, COSV53846608; called by muse, mutect2, varscan2
- PDZD2 | c.5532C>T p.G1844= | Silent (SNP) | VAF 212/437 reads (49%) | catalogued as rs776990963, COSV56855312; called by muse, mutect2, varscan2
- PHLDB1 | c.3801C>T p.G1267= | Silent (SNP) | VAF 112/304 reads (37%) | catalogued as rs782463191; called by muse, mutect2, varscan2
- PLCH1 | c.492T>C p.I164= (on ENST00000340059 / NM_001130960.2; = p.I176= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 316/711 reads (44%) | called by muse, mutect2, varscan2
- POLD1 | c.2670G>A p.A890= | Silent (SNP) | VAF 163/371 reads (44%) | catalogued as rs780344110; ClinVar: likely benign; called by muse, varscan2
- POLR3GL | c.399C>T p.L133= | Silent (SNP) | VAF 316/766 reads (41%) | catalogued as rs369727512; called by muse, mutect2, varscan2
- PPFIBP2 | c.175C>T p.L59= | Silent (SNP) | VAF 258/610 reads (42%) | called by muse, mutect2, varscan2
- PPM1A | c.567C>T p.G189= | Silent (SNP) | VAF 186/461 reads (40%) | catalogued as rs767681089; called by muse, mutect2, varscan2
- PRDM14 | c.720A>G p.Q240= | Silent (SNP) | VAF 180/482 reads (37%) | catalogued as rs750741522; called by muse, mutect2
- PRICKLE1 | c.1977C>T p.R659= | Silent (SNP) | VAF 160/385 reads (42%) | catalogued as rs1405666356, COSV58204544; called by muse, mutect2, varscan2
- PROS1 | c.1008C>T p.G336= | Silent (SNP) | VAF 193/478 reads (40%) | catalogued as rs141208672; called by muse, mutect2, varscan2
- PUM3 | c.736C>T p.L246= | Silent (SNP) | VAF 244/634 reads (38%) | called by muse, mutect2, varscan2
- RABGGTA | c.474G>T p.V158= | Silent (SNP) | VAF 194/468 reads (41%) | called by muse, mutect2, varscan2
- RALGPS1 | c.123C>T p.A41= | Silent (SNP) | VAF 192/452 reads (42%) | catalogued as rs752100811, COSV99401002; called by muse, mutect2, varscan2
- RASSF4 | c.294G>A p.S98= | Silent (SNP) | VAF 98/875 reads (11%) | catalogued as rs374262152, COSV58484290; called by muse, mutect2, varscan2
- RBMXL2 | c.702G>A p.S234= | Silent (SNP) | VAF 137/297 reads (46%) | catalogued as rs1190794791, COSV60978927; called by muse, mutect2, varscan2
- RFX2 | c.2067C>T p.G689= | Silent (SNP) | VAF 194/424 reads (46%) | catalogued as rs368023215; called by muse, mutect2, varscan2
- RGS20 | c.276A>C p.R92= | Silent (SNP) | VAF 106/291 reads (36%) | called by muse, mutect2, varscan2
- ROBO2 | c.177G>A p.T59= | Silent (SNP) | VAF 161/390 reads (41%) | catalogued as rs762225187, COSV59907559; called by muse, mutect2, varscan2
- RYR1 | c.1164G>A p.S388= | Silent (SNP) | VAF 188/379 reads (50%) | catalogued as rs770740642, COSV100617043; called by muse, mutect2, varscan2
- RYR1 | c.14817C>T p.D4939= | Silent (SNP) | VAF 199/465 reads (43%) | catalogued as rs193922895, CM043571, COSV62100628; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD1 | c.372G>A p.Q124= | Silent (SNP) | VAF 20/139 reads (14%) | called by muse, varscan2
- SART3 | c.99G>A p.R33= | Silent (SNP) | VAF 207/464 reads (45%) | catalogued as rs762987142, COSV57207341; called by muse, mutect2, varscan2
- SESN3 | c.573A>G p.V191= | Silent (SNP) | VAF 197/418 reads (47%) | called by muse, mutect2, varscan2
- SETD1A | c.1926G>A p.P642= | Silent (SNP) | VAF 91/220 reads (41%) | catalogued as rs777902844, COSV52686866; called by mutect2, varscan2
- SLC20A2 | c.1350C>T p.G450= | Silent (SNP) | VAF 174/423 reads (41%) | catalogued as rs1008551309, COSV60603200; called by muse, mutect2, varscan2
- SLC22A8 | c.1095C>T p.V365= | Silent (SNP) | VAF 175/359 reads (49%) | catalogued as rs375802571; called by muse, mutect2, varscan2
- SLC29A4 | c.897G>A p.P299= | Silent (SNP) | VAF 237/595 reads (40%) | catalogued as rs560946430; called by muse, mutect2, varscan2
- SLC35D3 | c.687C>T p.F229= | Silent (SNP) | VAF 176/465 reads (38%) | catalogued as rs757963261; called by muse, mutect2, varscan2
- SLC43A2 | c.1579C>T p.L527= | Silent (SNP) | VAF 131/357 reads (37%) | called by muse, mutect2, varscan2
- SLC5A2 | c.1878G>A p.P626= | Silent (SNP) | VAF 148/371 reads (40%) | catalogued as rs763032828, COSV57892093; called by muse, mutect2, varscan2
- SLC6A16 | c.255G>A p.T85= | Silent (SNP) | VAF 161/403 reads (40%) | catalogued as rs372873509; called by muse, mutect2, varscan2
- SLC6A19 | c.453C>T p.S151= | Silent (SNP) | VAF 128/281 reads (46%) | catalogued as rs756989097; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC7A9 | c.639C>T p.G213= | Silent (SNP) | VAF 226/626 reads (36%) | catalogued as rs763216072, COSV99195207; ClinVar: uncertain significance; called by muse, mutect2
- SMAD4 | c.1185T>C p.G395= | Silent (SNP) | VAF 172/481 reads (36%) | called by muse, mutect2, varscan2
- SMAP1 | c.1053A>G p.A351= (on ENST00000370455 / NM_001044305.3; = p.A324= on NM_021940.5) | Silent (SNP) | VAF 25/677 reads (4%) | called by muse, mutect2
- SMARCA2 | c.9G>A p.T3= | Silent (SNP) | VAF 153/374 reads (41%) | catalogued as rs775432878, COSV61805979; called by muse, mutect2, varscan2
- SMTNL1 | c.945C>T p.I315= (on ENST00000399154; = p.I352= on NM_001105565.2) | Silent (SNP) | VAF 201/459 reads (44%) | catalogued as rs955335008; called by muse, mutect2, varscan2
- SPINK4 | c.252C>T p.G84= | Silent (SNP) | VAF 280/729 reads (38%) | called by muse, mutect2, varscan2
- SPRED2 | c.1035C>T p.C345= | Silent (SNP) | VAF 161/381 reads (42%) | catalogued as rs765512116, COSV62693311; called by muse, mutect2, varscan2
- SPTBN4 | c.4758C>T p.S1586= | Silent (SNP) | VAF 119/250 reads (48%) | called by muse, mutect2, varscan2
- SRGAP1 | c.981T>C p.C327= | Silent (SNP) | VAF 168/396 reads (42%) | called by muse, mutect2, varscan2
- STARD13 | c.993C>T p.G331= (on ENST00000336934 / NM_001243476.3; = p.G213= on NM_052851.3) | Silent (SNP) | VAF 217/491 reads (44%) | catalogued as rs143886031; called by muse, mutect2, varscan2
- STOML3 | c.834C>T p.G278= | Silent (SNP) | VAF 165/404 reads (41%) | catalogued as rs748546865, COSV65509895; called by muse, mutect2, varscan2
- SURF6 | c.585G>A p.P195= | Silent (SNP) | VAF 184/405 reads (45%) | catalogued as rs374646780; called by muse, mutect2, varscan2
- SV2A | c.1059G>A p.T353= | Silent (SNP) | VAF 139/335 reads (41%) | catalogued as rs762634635; called by muse, mutect2, varscan2
- SYNE1 | c.7173C>T p.A2391= (on ENST00000367255 / NM_182961.4; = p.A2398= on NM_033071.3) | Silent (SNP) | VAF 248/586 reads (42%) | catalogued as rs774341012, COSV55038620; called by muse, mutect2, varscan2
- TADA3 | c.927G>A p.P309= | Silent (SNP) | VAF 241/546 reads (44%) | catalogued as rs375495645; called by muse, mutect2, varscan2
- TAF1 | c.2487C>T p.C829= (on ENST00000373790 / NM_138923.4; = p.C850= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 193/458 reads (42%) | catalogued as COSV52108385; called by muse, mutect2, varscan2
- TANC1 | c.4509G>A p.S1503= | Silent (SNP) | VAF 182/471 reads (39%) | catalogued as rs761006466; called by muse, varscan2
- TET3 | c.3966C>T p.H1322= | Silent (SNP) | VAF 67/142 reads (47%) | catalogued as rs768193705; called by muse, mutect2, varscan2
- TFB1M | c.510T>C p.T170= | Silent (SNP) | VAF 234/519 reads (45%) | called by muse, mutect2, varscan2
- TFDP1 | c.753G>A p.P251= | Silent (SNP) | VAF 154/328 reads (47%) | catalogued as rs201874910, COSV100945892, COSV64743138; called by muse, varscan2
- TMEM81 | c.675G>A p.A225= | Silent (SNP) | VAF 208/449 reads (46%) | catalogued as rs374746495; called by muse, mutect2, varscan2
- TMPO | c.1053G>A p.S351= | Silent (SNP) | VAF 156/353 reads (44%) | catalogued as rs375628010; called by muse, mutect2, varscan2
- TNS3 | c.237G>A p.P79= | Silent (SNP) | VAF 126/288 reads (44%) | catalogued as rs199837393; called by muse, mutect2, varscan2
- TPP1 | c.1488C>T p.G496= | Silent (SNP) | VAF 139/359 reads (39%) | catalogued as rs1315316303; called by muse, mutect2, varscan2
- TRIM77 | c.1122T>C p.G374= | Silent (SNP) | VAF 234/490 reads (48%) | catalogued as rs1014666333; called by muse, mutect2, varscan2
- TTK | c.2565A>G p.G855= | Silent (SNP) | VAF 226/609 reads (37%) | catalogued as rs961166327, COSV57882295; called by muse, mutect2, varscan2
- TTPAL | c.696T>C p.F232= | Silent (SNP) | VAF 284/714 reads (40%) | catalogued as rs1395968544; called by muse, mutect2, varscan2
- TUBB4A | c.327C>T p.G109= | Silent (SNP) | VAF 259/643 reads (40%) | catalogued as rs774127285; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBR4 | c.14943C>T p.G4981= | Silent (SNP) | VAF 185/410 reads (45%) | catalogued as rs1470502433; called by muse, mutect2, varscan2
- USF3 | c.5259A>G p.Q1753= | Silent (SNP) | VAF 172/457 reads (38%) | catalogued as rs753083381, COSV57075192; called by muse, mutect2, varscan2
- WASL | c.1107G>A p.G369= | Silent (SNP) | VAF 217/529 reads (41%) | catalogued as rs753301742; called by muse, mutect2, varscan2
- WDR7 | c.2802T>G p.G934= | Silent (SNP) | VAF 194/491 reads (40%) | called by muse, mutect2, varscan2
- WNK2 | c.1401C>T p.D467= | Silent (SNP) | VAF 174/418 reads (42%) | called by muse, mutect2, varscan2
- ZBTB20 | c.594C>T p.G198= (on ENST00000474710 / NM_001164342.2; = p.G125= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 77/223 reads (35%) | catalogued as rs776067488, COSV61852171; called by muse, mutect2, varscan2
- ZBTB7B | c.579A>G p.P193= (on ENST00000292176; = p.P227= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/148 reads (49%) | called by muse, mutect2, varscan2
- ZC3H10 | c.171A>G p.R57= | Silent (SNP) | VAF 62/188 reads (33%) | called by muse, mutect2, varscan2
- ZDHHC20 | c.915T>C p.S305= | Silent (SNP) | VAF 147/350 reads (42%) | called by muse, mutect2, varscan2
- ZMYM3 | c.2661G>A p.P887= | Silent (SNP) | VAF 161/354 reads (45%) | catalogued as rs750006813, COSV58736451; called by muse, mutect2, varscan2
- ZNF274 | c.120G>A p.R40= | Silent (SNP) | VAF 126/373 reads (34%) | called by muse, mutect2, varscan2
- ZNF282 | c.1716G>A p.R572= | Silent (SNP) | VAF 85/234 reads (36%) | called by muse, mutect2, varscan2
- ZNF462 | c.2718C>T p.G906= | Silent (SNP) | VAF 213/458 reads (47%) | catalogued as rs753932400; called by muse, mutect2, varscan2
- ZNF649 | c.945G>A p.E315= | Silent (SNP) | VAF 165/375 reads (44%) | called by muse, mutect2, varscan2
- ZNF785 | c.1098C>T p.S366= | Silent (SNP) | VAF 140/286 reads (49%) | catalogued as rs754271979, COSV67876311; called by muse, mutect2, varscan2
- ABCD4 | chr14:74303009 C>T | 5'Flank (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- ABHD12 | c.*88del | 3'UTR (DEL) | VAF 36/94 reads (38%) | called by mutect2, varscan2
- AC027559.1 | n.178C>T | RNA (SNP) | VAF 16/92 reads (17%) | catalogued as rs1451508184; called by muse, mutect2, varscan2
- AC073140.2 | n.532T>C | RNA (SNP) | VAF 186/437 reads (43%) | called by muse, mutect2, varscan2
- ACOXL | c.*27del | 3'UTR (DEL) | VAF 101/212 reads (48%) | called by mutect2, varscan2
- ADCY1 | c.1605+2246G>A | Intron (SNP) | VAF 18/42 reads (43%) | catalogued as rs945929732; called by muse, mutect2, varscan2
- ADGRA2 | c.*24C>T | 3'UTR (SNP) | VAF 54/110 reads (49%) | catalogued as rs1222172157; called by muse, mutect2, varscan2
- ADSS1 | c.193-5202G>A | Intron (SNP) | VAF 4/10 reads (40%) | catalogued as rs1326098431; called by muse, mutect2
- AICDA | c.427+54C>T | Intron (SNP) | VAF 50/91 reads (55%) | catalogued as rs778974972; called by muse, mutect2, varscan2
- AIG1 | c.399+22562del | Intron (DEL) | VAF 66/152 reads (43%) | called by mutect2, varscan2
- APOC2 | c.-13-62C>T | Intron (SNP) | VAF 21/53 reads (40%) | catalogued as rs1019794499; called by muse, mutect2, varscan2
- ARAP1 | c.1992+36A>G | Intron (SNP) | VAF 68/170 reads (40%) | called by muse, varscan2
- ARHGAP32 | c.1484+65del | Intron (DEL) | VAF 43/96 reads (45%) | catalogued as rs558334935; called by mutect2, varscan2
- ASXL3 | c.*1893del | 3'UTR (DEL) | VAF 63/148 reads (43%) | called by mutect2, varscan2
- ASZ1 | chr7:117427494 G>A | 5'Flank (SNP) | VAF 8/93 reads (9%) | catalogued as COSV99497977, COSV99497999; called by muse, mutect2
- ATAD3B | c.*185G>A | 3'UTR (SNP) | VAF 199/485 reads (41%) | catalogued as rs144490908; called by muse, mutect2, varscan2
- ATG4B | c.733-92C>T | Intron (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- ATP13A1 | c.907-33C>T | Intron (SNP) | VAF 123/280 reads (44%) | catalogued as rs781303537, COSV52287959; called by muse, mutect2, varscan2
- B3GAT3 | c.83-437G>A | Intron (SNP) | VAF 122/319 reads (38%) | called by muse, mutect2, varscan2
- BAGE2 | n.301C>T | RNA (SNP) | VAF 27/166 reads (16%) | called by muse, varscan2
- BUB1B | c.2679-69del | Intron (DEL) | VAF 32/44 reads (73%) | catalogued as rs144513398; called by mutect2, varscan2
- C17orf107 | c.*211G>A | 3'UTR (SNP) | VAF 55/107 reads (51%) | catalogued as rs374963791; called by muse, mutect2, varscan2
- C17orf107 | c.*698del | 3'UTR (DEL) | VAF 24/61 reads (39%) | called by mutect2, varscan2
- C1QB | c.*27G>A | 3'UTR (SNP) | VAF 45/129 reads (35%) | catalogued as rs770367483; called by muse, mutect2, varscan2
- C22orf23 | c.104-35G>A | Intron (SNP) | VAF 54/139 reads (39%) | catalogued as rs1213961232; called by muse, mutect2, varscan2
- CACNA1H | c.*46del | 3'UTR (DEL) | VAF 48/124 reads (39%) | called by mutect2, varscan2
- CALHM6 | c.-77T>A | 5'UTR (SNP) | VAF 149/330 reads (45%) | catalogued as rs1045095385; called by muse, mutect2, varscan2
- CCDC85C | c.*4440del | 3'UTR (DEL) | VAF 58/130 reads (45%) | called by mutect2, varscan2
- CCKBR | c.811+52C>T | Intron (SNP) | VAF 128/266 reads (48%) | catalogued as COSV58102125; called by muse, mutect2, varscan2
- CD72 | c.353-9G>A | Intron (SNP) | VAF 181/433 reads (42%) | called by muse, mutect2, varscan2
- CD86 | c.64+91T>G | Intron (SNP) | VAF 58/148 reads (39%) | called by muse, mutect2, varscan2
- CEACAM19 | c.-32G>A | 5'UTR (SNP) | VAF 57/138 reads (41%) | catalogued as rs749708976; called by muse, mutect2, varscan2
- CEP290 | c.6012-77del | Intron (DEL) | VAF 44/92 reads (48%) | called by mutect2, varscan2
- CEP290 | c.441+18del | Intron (DEL) | VAF 122/258 reads (47%) | catalogued as rs543419084; called by mutect2, varscan2
- CHTF8 | c.142-59G>A | Intron (SNP) | VAF 29/67 reads (43%) | catalogued as rs868453862; called by muse, mutect2, varscan2
- CIITA | c.3318-52del | Intron (DEL) | VAF 20/58 reads (34%) | called by mutect2, varscan2
- CNDP2 | c.367+12G>A | Intron (SNP) | VAF 144/341 reads (42%) | catalogued as rs749928247; called by muse, mutect2, varscan2
- CRACR2A | c.*4T>G | 3'UTR (SNP) | VAF 185/455 reads (41%) | called by muse, mutect2, varscan2
- CREB3L2 | c.103-29377C>T | Intron (SNP) | VAF 212/522 reads (41%) | catalogued as rs150390710; called by muse, mutect2, varscan2
- CRYBB1 | c.432+41G>C | Intron (SNP) | VAF 53/148 reads (36%) | called by muse, varscan2
- CTBP2 | c.58+11836C>T | Intron (SNP) | VAF 81/113 reads (72%) | catalogued as rs553177093; called by muse, mutect2, varscan2
- CUTA | c.*4G>A | 3'UTR (SNP) | VAF 199/449 reads (44%) | catalogued as rs374614248; called by muse, mutect2, varscan2
- CX3CR1 | chr3:39281731 G>A | 5'Flank (SNP) | VAF 78/240 reads (33%) | catalogued as rs542866644; called by muse, mutect2
- DBP | c.-2C>T | 5'UTR (SNP) | VAF 166/394 reads (42%) | called by muse, mutect2, varscan2
- DCBLD2 | c.571+70del | Intron (DEL) | VAF 68/140 reads (49%) | catalogued as rs780707032; called by mutect2, varscan2
- DCX | c.-22-27A>G | Intron (SNP) | VAF 72/85 reads (85%) | called by muse, mutect2, varscan2
- DNAH12 | c.6929+23219C>T | Intron (SNP) | VAF 232/531 reads (44%) | catalogued as rs1164235202; called by muse, mutect2, varscan2
- DNAH2 | c.6603+52C>T | Intron (SNP) | VAF 135/391 reads (35%) | catalogued as rs904002735; called by muse, mutect2, varscan2
- DNAJB1 | c.792+35C>T | Intron (SNP) | VAF 56/117 reads (48%) | called by muse, mutect2, varscan2
- DPYD | c.*49C>T | 3'UTR (SNP) | VAF 88/199 reads (44%) | called by muse, mutect2, varscan2
- DUOX2 | c.1398+64C>A | Intron (SNP) | VAF 37/42 reads (88%) | called by muse, mutect2, varscan2
- DUS3L | chr19:5791168 T>G | 5'Flank (SNP) | VAF 55/131 reads (42%) | called by muse, mutect2, varscan2
- EPG5 | c.4329+12G>A | Intron (SNP) | VAF 173/529 reads (33%) | called by muse, mutect2, varscan2
- EPHA4 | c.2075-71C>T | Intron (SNP) | VAF 53/133 reads (40%) | catalogued as rs1318207364; called by muse, mutect2, varscan2
- ERCC3 | c.657+18C>T | Intron (SNP) | VAF 220/538 reads (41%) | called by muse, mutect2, varscan2
- ESD | c.*54C>T | 3'UTR (SNP) | VAF 67/124 reads (54%) | called by muse, mutect2, varscan2
- EXOSC2 | c.*60G>A | 3'UTR (SNP) | VAF 121/237 reads (51%) | called by muse, mutect2, varscan2
- FBXO33 | c.*64del | 3'UTR (DEL) | VAF 18/43 reads (42%) | catalogued as rs926634185; called by mutect2, varscan2
- FBXO5 | c.909+67_909+69del | Intron (DEL) | VAF 64/160 reads (40%) | called by mutect2, varscan2
- FCSK | c.485-89G>A | Intron (SNP) | VAF 6/17 reads (35%) | catalogued as rs944181148; called by muse, mutect2, varscan2
- FRMD4B | c.-11_-9del | 5'UTR (DEL) | VAF 110/246 reads (45%) | called by mutect2, varscan2
- GGCT | c.424-485C>T | Intron (SNP) | VAF 43/627 reads (7%) | catalogued as rs779240265; called by muse, mutect2
- GIMAP8 | c.*60G>A | 3'UTR (SNP) | VAF 31/78 reads (40%) | catalogued as rs964650729, COSV100217663; called by muse, mutect2, varscan2
- GNAL | chr18:11884435 C>T | 3'Flank (SNP) | VAF 144/385 reads (37%) | catalogued as rs373020731, COSV52324632; called by muse, mutect2, varscan2
- GOLGA8H | c.310-36G>A | Intron (SNP) | VAF 68/141 reads (48%) | catalogued as rs1475324428; called by muse, mutect2, varscan2
- GSDMD | c.411-74C>T | Intron (SNP) | VAF 19/33 reads (58%) | catalogued as rs1240955178; called by muse, mutect2, varscan2
- GVQW3 | c.382+218dup | Intron (INS) | VAF 184/450 reads (41%) | catalogued as rs1025167575; called by mutect2, varscan2
- H2BC15 | chr6:27838631 T>C | 5'Flank (SNP) | VAF 126/271 reads (46%) | catalogued as rs1420333353; called by muse, mutect2, varscan2
- HAT1 | c.717-85A>G | Intron (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- HDAC7 | c.2239-21C>G | Intron (SNP) | VAF 55/116 reads (47%) | called by muse, mutect2, varscan2
103 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 103 other) are not listed here.
